Surgical pathology report (de-identified scan), TCGA case TCGA-S6-A8JY, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Gundersen Lutheran Health System, specimen TCGA-S6-A8JY-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]
Med. Record. No.: [REDACTED] Age: [REDACTED]
Date of Birth: [REDACTED] Sex: M
Submitted by: [REDACTED]
Report also to: [REDACTED]

Pathology #: [REDACTED]
Date of Procedure: [REDACTED]
Date Received: [REDACTED]

Pathology Report

DIAGNOSIS:

ICD-O-3
Seminoma NOS 9061/3
Site (L) Testis NOS C62.9
JW 1/29/14

SPECIMEN

Specimen type: Left radical orchiectomy

TUMOR

Histologic type: Seminoma
Tumor size (greatest dimension): 3.5cm
Tumor focality: Multifocal
Involvement of rete testis: Present
Venous/lymphatic invasion: Absent
Extent of direct tumor invasion: No direct tumor extension beyond testis
Additional findings: Intratubular germ cell neoplasia

MARGINS

All margins negative for tumor

LYMPH NODES

Cannot be assessed

SERUM TUMOR MARKERS

S3: LDH >10 x nl or HCG >50,000 or AFP >10,000

STAGING (AJCC)

Primary Tumor: pT1
Lymph Nodes: pNX
Distant Metastasis: Cannot be assessed

CLINICAL INFORMATION:

Left testis mass. Also palpable abdominal/retroperitoneal mass, likely metastasis.
Serum tumor markers:
LDH > 2500 IU/L
hCG 65 U/L
AFP pending.

[page 2 of 2]
Patient: [REDACTED]

MRN: [REDACTED]

SPECIMEN(S) RECEIVED:

Left testicle and cord.

research specimen.

GROSS DESCRIPTION:

Received in formalin is a 76.2-gram radical orchiectomy specimen with 6.0 x 4.2 x 3.2 cm testis, 5.5 x 1.5 x 0.8 cm epididymis and 18.5 x 2.0 cm spermatic cord. The testis is enveloped by a thin and membranous tunica vaginalis which retracts with ease. The tunica albuginea is smooth and pink-white. The testicular parenchyma is largely occupied by two masses. The more superior mass measuring 3.0 x 2.8 x 2.1 cm is multinodular and tan-gray with extensive necrosis. The mass extends to but does not penetrate through the tunica albuginea. The second mass involves the inferior portion of the testis, measures 3.5 x 3.0 x 2.5 cm and has a solid, uniformly smooth, tan-pink cut surface. The inferior pole mass lies slightly more posterior than the inferior pole mass, adjacent to the rete testis. The surrounding parenchyma is spongy and pink-brown. The epididymis is unremarkable. The spermatic cord is unremarkable. There is no macroscopic involvement of the spermatic cord by tumor. The specimen is photographed. Tissue is collected from each mass along with normal testicular parenchyma for the

Sections submitted: A1-A2 – partially necrotic mass, superior testis; A3 – section representing interface between the two masses; A4-A6 – mass of inferior testis to include rete testis; A7 – normal testis and epididymis; A8 – proximal spermatic cord; A9 – mid spermatic cord; A10 – distal spermatic cord margin.

Immunohistochemistry Results

Formalin-fixed, paraffin-embedded tissue is utilized. Tissue sections are incubated with the following antibodies. Controls stain appropriately. Complete procedural methodology is available upon request. Results indicated below:

Material: Block A6

Marker For:	Result	Comment
Placental alkaline phosphatase (PLAP)	Positive	
Human chorionic gonadotropin (HCG)	Negative	
Alpha-fetoprotein (AFP)	Negative	
CD30	Negative	
Cytokeratins (pan-keratin cocktail)	Negative	

Note: The performance characteristics of all immunohistochemical stains cited in this report were determined by the as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88). Some of these tests may rely on the use of "analyte specific reagents" and have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to this report. These tests are used for clinical purposes, and should not be regarded as investigational or for research. The immunohistochemistry laboratory at [REDACTED] is certified by the Centers for Medicare and Medicaid Services (formerly HCFA) as a high complexity laboratory under CLIA '88.

Slides were microscopically examined by the pathologist.

Evaluation performed by [REDACTED]

Electronically signed [REDACTED]

Criteria	W 11/14/13	Yes	No
HIV+/- Discrepancy			

Source: NCI Genomic Data Commons file 738181c5-99bd-4fe0-98ef-d8972238058f (TCGA-S6-A8JY.1158007C-334D-40AC-9964-CF87A1C6E756.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).